TCGA case TCGA-ZN-A9VV — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Brigham and Women's Hospital Division of Thoracic Surgery. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cb94a8ae-2b0c-4d0b-ada3-4c82dd765567

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (3)
1. Mesothelioma, biphasic, malignant (the primary disease): ICD-O-3 morphology code: 9053/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.7 years (25,096 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,309 days (3.6 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Pemetrexed Disodium; Days to treatment start: 190 days; Days to treatment end: 270 days.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Pleura, NOS. Age at diagnosis: 70.6 years (25,772 days); Days to diagnosis: 676 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Progression of diagnosis 1 (Mesothelioma, biphasic, malignant), site: Lung, NOS. Age at diagnosis: 72.3 years (26,395 days); Days to diagnosis: 1,299 days (3.6 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Day 676 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Pleura, NOS; Days to progression: 676 days (1.9 years).
- Day 1,299 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,299 days (3.6 years).
- Days to follow up: 1,309 days (3.6 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 6.1; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Creatinine 1.11 mg/dL [Blood test normal range lower: 0.5; Blood test normal range upper: 1.2].

Exposures
- Occupation type: Machinery Mechanics and Repairers.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ZN-A9VV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 260 mg.
  Slide TCGA-ZN-A9VV-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-ZN-A9VV-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ZN-A9VV-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; Primary occupation: Automotive.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Biphasic mesothelioma.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment 2: Pharmaceutical therapy drug name: Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,309 days; disease-specific survival: no event (censored), 1,309 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 676 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ZN-A9VV-01A-11D-A39Q-01): tumor purity 0.96, ploidy 1.97, whole-genome doublings 0.
